MMRF case MMRF_1537 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/0f7bd3fb-8fe8-4c22-a9d1-945053dd213d

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 62 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 62.8 years (22,931 days); ISS stage: III; Days to last known disease status: 1,239 days (3.4 years); Days to last follow up: 1,239 days (3.4 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 52 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -12 (ECOG 1): M Protein 1.22 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 8 mg/dL; Immunoglobulin G 6.39 g/L; Immunoglobulin A 18.7 g/L; Immunoglobulin M 0.49 g/L; Beta 2 Microglobulin 5.67 µg/mL; Lactate Dehydrogenase 2.18 µkat/L; Hemoglobin 5.95 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 4.4 ×10⁹/L; Platelets 198 ×10⁹/L; Creatinine 229 µmol/L; Blood Urea Nitrogen 25 mmol/L; Calcium 2.53 mmol/L; Albumin 39 g/L; Total Protein 7.8 g/dL; Glucose 6.44 mmol/L; C-Reactive Protein 0.5 mg/dL.
- Day 81 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.72 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.63 mg/dL; Immunoglobulin G 2.2 g/L; Immunoglobulin A 0.22 g/L; Immunoglobulin M 0.16 g/L; Lactate Dehydrogenase 2.68 µkat/L; Hemoglobin 6.01 mmol/L; Leukocytes 6.6 ×10⁹/L; Absolute Neutrophil 5.2 ×10⁹/L; Platelets 151 ×10⁹/L; Creatinine 163 µmol/L; Blood Urea Nitrogen 22.5 mmol/L; Calcium 2.13 mmol/L; Albumin 34 g/L; Total Protein 4.7 g/dL; Glucose 10.7 mmol/L.
- Day 191 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.96 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.67 mg/dL; Immunoglobulin G 4.04 g/L; Immunoglobulin A 0.64 g/L; Immunoglobulin M 0.3 g/L; Beta 2 Microglobulin 4.21 µg/mL; Hemoglobin 6.94 mmol/L; Leukocytes 8.8 ×10⁹/L; Absolute Neutrophil 6.9 ×10⁹/L; Platelets 149 ×10⁹/L; Creatinine 180 µmol/L; Blood Urea Nitrogen 16.8 mmol/L; Calcium 2.35 mmol/L; Albumin 41 g/L; Total Protein 6.3 g/dL; Glucose 6.16 mmol/L.
- Day 247 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.44 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.53 mg/dL; Immunoglobulin G 4.15 g/L; Immunoglobulin A 1.19 g/L; Immunoglobulin M 0.34 g/L; Hemoglobin 7.13 mmol/L; Leukocytes 7.5 ×10⁹/L; Absolute Neutrophil 5.7 ×10⁹/L; Platelets 192 ×10⁹/L; Creatinine 178 µmol/L; Blood Urea Nitrogen 16.4 mmol/L; Calcium 2.35 mmol/L; Albumin 42 g/L; Total Protein 6.4 g/dL; Glucose 8.97 mmol/L.
- Day 331: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.97 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.97 mg/dL; Beta 2 Microglobulin 4.9 µg/mL; Lactate Dehydrogenase 7.27 µkat/L; Hemoglobin 6.63 mmol/L; Leukocytes 6.5 ×10⁹/L; Absolute Neutrophil 4.9 ×10⁹/L; Platelets 167 ×10⁹/L; Creatinine 194 µmol/L; Blood Urea Nitrogen 15 mmol/L; Calcium 2.38 mmol/L; Albumin 41 g/L; Total Protein 6.3 g/dL; Glucose 4.73 mmol/L.
- Day 469 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.21 mg/dL; Immunoglobulin G 4.5 g/L; Immunoglobulin A 1.05 g/L; Immunoglobulin M 0.44 g/L; Beta 2 Microglobulin 3.76 µg/mL; Lactate Dehydrogenase 7.77 µkat/L; Hemoglobin 6.7 mmol/L; Leukocytes 6.7 ×10⁹/L; Absolute Neutrophil 5 ×10⁹/L; Platelets 168 ×10⁹/L; Creatinine 180 µmol/L; Blood Urea Nitrogen 18.6 mmol/L; Calcium 2.35 mmol/L; Albumin 39 g/L; Total Protein 6.3 g/dL; Glucose 4.13 mmol/L.
- Day 686 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.05 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.62 mg/dL; Immunoglobulin G 5.5 g/L; Immunoglobulin A 1.32 g/L; Immunoglobulin M 0.56 g/L; Lactate Dehydrogenase 3.37 µkat/L; Hemoglobin 6.51 mmol/L; Leukocytes 7.9 ×10⁹/L; Absolute Neutrophil 5.8 ×10⁹/L; Platelets 164 ×10⁹/L; Creatinine 224 µmol/L; Blood Urea Nitrogen 20.7 mmol/L; Calcium 2.25 mmol/L; Albumin 45 g/L; Total Protein 6.5 g/dL; Glucose 5.34 mmol/L.
- Day 791 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.97 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.21 mg/dL; Immunoglobulin G 5.03 g/L; Immunoglobulin A 1.42 g/L; Immunoglobulin M 0.52 g/L; Lactate Dehydrogenase 3.18 µkat/L; Hemoglobin 6.94 mmol/L; Leukocytes 8.9 ×10⁹/L; Absolute Neutrophil 6.7 ×10⁹/L; Platelets 166 ×10⁹/L; Creatinine 194 µmol/L; Blood Urea Nitrogen 18.2 mmol/L; Calcium 2.35 mmol/L; Albumin 40 g/L; Total Protein 5.9 g/dL; Glucose 4.73 mmol/L.
- Day 882 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.46 mg/dL; Immunoglobulin G 5.78 g/L; Immunoglobulin A 1.66 g/L; Immunoglobulin M 0.58 g/L; Lactate Dehydrogenase 3.05 µkat/L; Hemoglobin 6.94 mmol/L; Leukocytes 7.8 ×10⁹/L; Absolute Neutrophil 5.8 ×10⁹/L; Platelets 180 ×10⁹/L; Creatinine 217 µmol/L; Blood Urea Nitrogen 20.7 mmol/L; Calcium 2.38 mmol/L; Albumin 43 g/L; Total Protein 6.6 g/dL; Glucose 7.26 mmol/L.
- Day 1,064 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.14 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.43 mg/dL; Immunoglobulin G 5.07 g/L; Immunoglobulin A 1.68 g/L; Immunoglobulin M 0.47 g/L; Lactate Dehydrogenase 2.97 µkat/L; Hemoglobin 6.63 mmol/L; Leukocytes 8.2 ×10⁹/L; Absolute Neutrophil 6.1 ×10⁹/L; Platelets 171 ×10⁹/L; Creatinine 222 µmol/L; Blood Urea Nitrogen 23.6 mmol/L; Calcium 2.25 mmol/L; Albumin 41 g/L; Total Protein 6.3 g/dL; Glucose 4.18 mmol/L.
- Day 1,239 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.73 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.93 mg/dL; Immunoglobulin G 5.7 g/L; Immunoglobulin A 2.08 g/L; Immunoglobulin M 0.82 g/L; Lactate Dehydrogenase 2.83 µkat/L; Hemoglobin 6.7 mmol/L; Leukocytes 7.1 ×10⁹/L; Absolute Neutrophil 5.4 ×10⁹/L; Platelets 144 ×10⁹/L; Creatinine 230 µmol/L; Blood Urea Nitrogen 20.7 mmol/L; Calcium 2.38 mmol/L; Albumin 42 g/L; Total Protein 6.6 g/dL; Glucose 3.19 mmol/L.

Other clinical attributes
- Day -12: Weight: 123 kg; Height: 177 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1537_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -12 days.
- Sample MMRF_1537_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -12 days.
